Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A051, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A051-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Right tube and ovary, cervix and uterus (fs)
- 2: SP: Left tube and ovary
- 3: SP: Left external iliac lymph node
- 4: SP: Left obturator lymph node
- 5: SP: Omentum bx

100-0-3

adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1
lw
5/2/11

DIAGNOSIS:

- 1-3) TUBES AND OVARIES, RIGHT AND LEFT, CERVIX AND UTERUS; TOTAL HYSTERECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE III, NUCLEAR GRADE III (SEE NOTE).
- THE TUMOR INVADES TO $\leq$ HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 10 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 27 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NABOTHIAN CYST.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITIES: ATROPHY AND COMPLEX HYPERPLASIA WITHOUT ATYPIA.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMA.
- ALL ADNEXAE ARE UNREMARKABLE.
- NO LYMPH NODES IDENTIFIED.

NOTE: THE OVERALL FIGO GRADE IS BASED IN PART ON THE APPEARANCE OF THE TUMOR IN THE PREVIOUS BIOPSY [REDACTED]. THIS CASE HAS BEEN REVIEWED BY DR. [REDACTED].

- 3) LYMPH NODES, LEFT EXTERNAL ILIAC; BIOPSY:
- MATURE ADIPOSE TISSUE.
- NO LYMPH NODE SEEN.
- 4) LYMPH NODE, LEFT OBTURATOR; BIOPSY:
- MATURE ADIPOSE TISSUE.
- NO LYMPH NODE SEEN.

** Continued on next page **

Print Malignancy History		
Case is (circled):		

lw 5/2/11

[page 2 of 2]
- 5) OMENTUM; BIOPSY:
- MATURE ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file f672f8c4-715b-4817-ae5d-5fd97719d726 (TCGA-AP-A051.2146A2FC-99EE-4939-AD9F-086BB77D2B21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).